Somatic mutation profile of tumor specimen TARGET-30-PATUWG-01A (aliquot TARGET-30-PATUWG-01A-01D) from TARGET case TARGET-30-PATUWG, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.0 years (1,448 days).
Specimen TARGET-30-PATUWG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e93bcf43-03e7-4ee1-a302-bf2336257866.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATUWG-10A (Blood Derived Normal), aliquot TARGET-30-PATUWG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/465bdd58-3e7c-4b02-883a-8fb1220c145c

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.2888A>G p.Y963C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67803482; called by muse, mutect2, varscan2
- CACNA1A | c.539+10G>A | Intron (SNP) | VAF 37/105 reads (35%) | catalogued as rs375079448; ClinVar: likely benign; called by muse, mutect2, varscan2
- GAREM1 | c.*2476G>T | 3'UTR (SNP) | VAF 69/186 reads (37%) | catalogued as rs1239530276, COSV52517533; called by muse, mutect2, varscan2
- PTBP1 | c.*1405C>G | 3'UTR (SNP) | VAF 74/227 reads (33%) | catalogued as COSV62462204; called by muse, mutect2, varscan2
